Somatic mutation profile of tumor specimen 0DH29L from CCDI case PBBUFR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,546 days).
Specimen 0DH29L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6b6e132-79e1-404d-ab7b-83c8228f2fc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH27K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7d620f4-9449-47f6-bde3-b42402c48688

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 5'UTR 1, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 38/176 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, varscan2
- SERPINA1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.301); catalogued as rs758820515, COSV100871980, COSV63345335; called by muse, mutect2
- COL11A1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRSS2 | c.237A>T p.E79D | Missense Mutation (SNP) | VAF 30/860 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- ZNF100 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 56/341 reads (16%) | called by muse, mutect2, varscan2
- ANKRD30A | c.2757A>G p.E919= (on ENST00000611781; = p.E863= on NM_052997.2) | Silent (SNP) | VAF 10/78 reads (13%) | called by mutect2, varscan2
- CBLN3 | c.-216T>A | 5'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- MSANTD2P1 | n.743T>A | RNA (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- NCAPH2 | c.861+113C>G | Intron (SNP) | VAF 4/60 reads (7%) | catalogued as rs998143555; called by muse, mutect2
